CCDI case PBCRLH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/08c559c5-9094-4484-800b-8f11f44e45c9

Demographics
Sex at birth: female.

Diagnoses (1)
1. Pleuropulmonary blastoma: ICD-O-3 morphology code: 8973/3; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 3.4 years (1,233 days).

Biospecimens (3 samples)
- Sample 0DY1PZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DY1QJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DY1R5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
